Somatic mutation profile of tumor specimen C3L-01252-01 (aliquot CPT0080610009) from CPTAC case C3L-01252, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 76.8 years (28,034 days).
Specimen C3L-01252-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 988563cc-0213-46bb-af3e-67843a238eb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01252-72 (Blood Derived Normal), aliquot CPT0080660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f3253ac-a14d-4e0c-b17f-99db7db2c38a

The open-access MAF lists 528 somatic variants for this specimen: 358 protein-altering or splice-affecting, 113 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 265, Silent 113, Frame Shift Del 68, Intron 28, Frame Shift Ins 10, 5'UTR 10, Nonsense Mutation 9, RNA 6, 3'UTR 5, 3'Flank 5, Splice Site 5, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 26/307 reads (8%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel
- ALOX12B | c.1350del p.L451Sfs*16 | Frame Shift Del (DEL) | VAF 54/532 reads (10%) | catalogued as rs746723399, COSV59872823; ClinVar: pathogenic; called by mutect2, pindel
- ANKRD11 | c.6792dup p.A2265Rfs*8 | Frame Shift Ins (INS) | VAF 15/66 reads (23%) | catalogued as rs878855327; ClinVar: pathogenic; called by mutect2, varscan2
- ARSA | c.302del p.G101Afs*7 | Frame Shift Del (DEL) | VAF 26/262 reads (10%) | catalogued as rs761606317, CM910050, CM990175; ClinVar: pathogenic; called by mutect2, pindel
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 48/461 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 37/433 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 104/656 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- MYO7A | c.1623dup p.K542Qfs*5 | Frame Shift Ins (INS) | VAF 31/284 reads (11%) | catalogued as rs782077721; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 40/354 reads (11%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel
- ABLIM2 | c.1596del p.C533Vfs*30 (on ENST00000341937 / NM_001130084.2; = p.C567Vfs*30 on NM_001130083.2) | Frame Shift Del (DEL) | VAF 12/153 reads (8%) | catalogued as COSV56410671; called by mutect2, pindel
- ACCSL | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs372214310; called by muse, mutect2, varscan2
- ACTN3 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 21/318 reads (7%) | catalogued as rs1208449597, COSV72207551; called by muse, mutect2
- ADAM11 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1445426610; called by muse, mutect2, varscan2
- ANKRD30A | c.2813G>T p.C938F (on ENST00000611781; = p.C882F on NM_052997.2) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as rs1387932160; called by muse, mutect2, varscan2
- ANKRD6 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs926915572, COSV100330239; called by muse, mutect2
- ARHGAP40 | c.492del p.L165Cfs*55 | Frame Shift Del (DEL) | VAF 18/179 reads (10%) | catalogued as rs780331526; called by mutect2, pindel
- ARHGAP44 | c.1713del p.A572Rfs*121 | Frame Shift Del (DEL) | VAF 8/94 reads (9%) | catalogued as rs1408409506; called by mutect2, pindel
- ARSF | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs377453092; called by muse, mutect2, varscan2
- ASTN1 | c.3622C>T p.R1208* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as rs967126995, COSV62503245; called by muse, mutect2
- ASXL1 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 51/868 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as COSV60119564; called by muse, mutect2
- BEND5 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1395610711, COSV100884074; called by muse, mutect2
- BORCS6 | c.766del p.I256Sfs*12 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | catalogued as rs751878342; called by mutect2, pindel
- BRCA1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as rs1301795658; ClinVar: uncertain significance; called by muse, mutect2
- C9orf135 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs764088063, COSV65875522; called by muse, mutect2, varscan2
- CABYR | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV100510008; called by muse, mutect2, varscan2
- CACNA1B | c.6979C>T p.R2327W | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs765789569, COSV53142151; called by muse, varscan2
- CACNA1D | c.6082G>A p.E2028K (on ENST00000350061 / NM_001128840.3; = p.E2048K on NM_000720.4) | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.03); catalogued as rs771286149, COSV55443014; called by muse, mutect2
- CAPRIN1 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 45/600 reads (8%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.464); catalogued as rs1309720008; called by muse, mutect2
- CARD6 | c.1132G>A p.V378M | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1249212767; called by muse, mutect2
- CASKIN1 | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs747282431; called by muse, mutect2, varscan2
- CBY2 | c.645del p.S216Rfs*14 | Frame Shift Del (DEL) | VAF 18/219 reads (8%) | catalogued as rs1566071752; called by mutect2, pindel
- CCDC144A | c.180C>A p.S60R | Missense Mutation (SNP) | VAF 42/338 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV61404570; called by muse, mutect2, varscan2
- CCDC166 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV72638691; called by muse, mutect2, varscan2
- CCDC168 | c.30del p.V12* | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | catalogued as COSV59505832; called by mutect2, varscan2
- CCDC88A | c.4235G>A p.R1412Q | Missense Mutation (SNP) | VAF 47/421 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV99710902; called by muse, mutect2, varscan2
- CCNYL1 | c.537G>T p.E179D (on ENST00000295414 / NM_001330218.2; = p.E109D on NM_152523.2) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs933412126; called by muse, mutect2, varscan2
- CDK16 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 28/394 reads (7%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.466); catalogued as rs777717613; called by muse, mutect2
- CDYL2 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.648); catalogued as rs772092026, COSV73647784; called by muse, varscan2
- CELSR1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 24/340 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs761345110, COSV53089573; called by muse, mutect2
- CEP192 | c.4889C>T p.T1630M | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs749692097, COSV58060205; called by muse, mutect2, varscan2
- CITED2 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1274837493, CM145552; called by muse, mutect2, varscan2
- CLSTN2 | c.1270G>A p.V424I | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.588); catalogued as rs762312951; called by muse, mutect2
- CNGB1 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 85/413 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as rs746847813; called by muse, mutect2, varscan2
- CNTNAP3 | c.2635G>A p.V879M | Missense Mutation (SNP) | VAF 19/451 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1298375215; called by muse, mutect2
- CNTNAP5 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 44/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1448342066, COSV70491153; called by muse, mutect2, varscan2
- COL18A1 | c.3356G>C p.G1119A (on ENST00000359759 / NM_130444.3; = p.G884A on NM_030582.4) | Missense Mutation (SNP) | VAF 63/536 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100645413; called by mutect2, varscan2
- COL2A1 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 46/580 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as CM160187; called by muse, mutect2
- COL9A2 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 26/904 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as rs1180754065; called by muse, mutect2
- DALRD3 | c.826G>A p.G276S (on ENST00000341949 / NM_001009996.3; = p.G109S on NM_018114.5) | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs547396126, COSV58244908; called by muse, mutect2
- DHRS1 | c.823T>C p.Y275H | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs1470536813; called by muse, mutect2, varscan2
- DIABLO | c.260C>T p.A87V (on ENST00000443649 / NM_001278303.1; = p.A160V on NM_019887.6) | Missense Mutation (SNP) | VAF 21/551 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1391765504; called by muse, mutect2
- DOCK2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); catalogued as rs752575256, COSV56958321; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 12/123 reads (10%) | catalogued as rs782552436; called by mutect2, pindel
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 13/149 reads (9%) | catalogued as rs1239294263; called by mutect2, pindel
- DUSP22 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 20/475 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1433506443; called by muse, mutect2
- DYSF | c.5281G>T p.V1761F | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1558778620; called by muse, mutect2
- EHMT2 | c.2467C>T p.H823Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs943939695; called by muse, mutect2, varscan2
- EML2 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1008165335; called by muse, mutect2
- ENGASE | c.1381G>T p.G461* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as COSV56135697; called by muse, mutect2
- ENPP1 | c.740del p.N247Tfs*2 | Frame Shift Del (DEL) | VAF 34/305 reads (11%) | catalogued as rs759257042, COSV100719662; called by mutect2, pindel, varscan2
- ESM1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101195716, COSV67318511; called by muse, mutect2, varscan2
- ESR2 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50830407, COSV50831495; called by muse, mutect2
- ESRP1 | c.555del p.N186Ifs*2 | Frame Shift Del (DEL) | VAF 6/74 reads (8%) | catalogued as COSV100619529; called by mutect2, pindel
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 29/226 reads (13%) | catalogued as rs775950025; called by mutect2, varscan2
- FAM102A | c.878G>A p.R293Q (on ENST00000373095 / NM_001035254.3; = p.R151Q on NM_203305.2) | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as rs1324837976; called by muse, mutect2
- FAM200B | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1042398618, COSV69959682; called by muse, mutect2, varscan2
- FAM47B | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 38/255 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs781229202, COSV61457625; called by muse, mutect2, varscan2
- FAT4 | c.6586G>A p.G2196S | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779072662; called by muse, mutect2, varscan2
- FBN1 | c.598A>G p.S200G | Missense Mutation (SNP) | VAF 30/814 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs1057036462; ClinVar: uncertain significance; called by muse, mutect2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 14/166 reads (8%) | catalogued as rs772353703; called by mutect2, pindel
- FBXO42 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as rs774332311; called by muse, mutect2
- FOXG1 | c.1261G>A p.V421I | Missense Mutation (SNP) | VAF 60/752 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100486520; called by muse, mutect2
- FUT7 | c.902G>A p.W301* | Nonsense Mutation (SNP) | VAF 24/458 reads (5%) | catalogued as COSV55805036; called by muse, mutect2
- GABRB2 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 13/375 reads (3%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs1034017582; called by muse, mutect2
- GALK2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs764331208; called by muse, mutect2, varscan2
- GET3 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100628134; called by muse, mutect2
- GRB10 | c.1771C>T p.R591* (on ENST00000398812; = p.R545* on NM_001001549.3) | Nonsense Mutation (SNP) | VAF 36/418 reads (9%) | catalogued as rs775842626, COSV60013275; called by muse, mutect2
- GTF3C1 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62241470; called by muse, mutect2, varscan2
- GYS1 | c.737G>T p.R246M | Missense Mutation (SNP) | VAF 47/489 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99620853; called by muse, mutect2
- HABP2 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs373829826; called by muse, mutect2
- HIVEP2 | c.4490G>A p.R1497Q | Missense Mutation (SNP) | VAF 38/373 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV99175624; called by muse, mutect2, varscan2
- HSPG2 | c.2303G>A p.G768D | Missense Mutation (SNP) | VAF 66/756 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161842684; called by muse, mutect2
- HUWE1 | c.4964G>A p.R1655Q | Missense Mutation (SNP) | VAF 31/463 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782782151, COSV53341705; called by muse, mutect2
- HYOU1 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781828975, COSV101345597, COSV68217470; called by muse, mutect2
- INPP5E | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1277886267; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 10/102 reads (10%) | catalogued as rs760925109; called by mutect2, pindel
- ITGAE | c.1795del p.A599Pfs*84 | Frame Shift Del (DEL) | VAF 50/459 reads (11%) | catalogued as COSV99560605, COSV99561817; called by mutect2, pindel, varscan2
- KCNA5 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 86/562 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767170268, COSV52908801; called by muse, mutect2, varscan2
- KHSRP | c.1608del p.P538Lfs*185 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs763740814; called by mutect2, pindel, varscan2
- KIF23 | c.2726G>A p.R909Q (on ENST00000260363; = p.R805Q on NM_004856.7) | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201461078; called by muse, mutect2
- KIFC3 | c.2152G>A p.V718M | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1555595842; called by muse, mutect2, varscan2
- KLHDC8B | c.48del p.M17Cfs*59 | Frame Shift Del (DEL) | VAF 21/201 reads (10%) | catalogued as rs756907493; called by mutect2, pindel
- KLK9 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775609805; called by muse, mutect2, varscan2
- LGR6 | c.662G>A p.R221H (on ENST00000367278 / NM_001017403.1; = p.R169H on NM_021636.3) | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs372287043; called by muse, mutect2, varscan2
- LMNA | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 45/449 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.34); catalogued as rs139875047; called by muse, mutect2
- LRIG1 | c.1694G>A p.R565H | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.167); catalogued as rs759019949; called by muse, mutect2
- LRP6 | c.4340G>C p.S1447T | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.223); catalogued as COSV53789148; called by muse, mutect2
- MADD | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 21/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1195327978, COSV100211611; called by muse, mutect2
- MAP7D2 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 82/536 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs747313218, COSV65528835; called by muse, mutect2, varscan2
- MDM1 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200544846, CM142481, COSV100291795, COSV57449588; called by muse, mutect2, varscan2
- MED17 | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1225529445; called by muse, mutect2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MYH10 | c.5534G>A p.R1845H | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs766707630; called by muse, mutect2
- MYO15A | c.2873del p.P958Lfs*28 | Frame Shift Del (DEL) | VAF 6/84 reads (7%) | catalogued as rs1217492313; called by mutect2, pindel
- NAP1L2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as rs759636463, COSV65172305; called by muse, mutect2
- NCAM1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs367901170; called by muse, mutect2
- NEFM | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 35/655 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV55330703; called by muse, mutect2
- NEURL1B | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179203760, COSV63940482; called by muse, mutect2
- NGEF | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs572634482, COSV50935521; called by muse, mutect2, varscan2
- NGF | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149823633; called by muse, mutect2
- NMUR1 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.609); catalogued as rs1315390935, COSV100531744; called by muse, mutect2, varscan2
- NOD1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047968307, COSV56111217; called by muse, mutect2
- NSD1 | c.3092G>A p.R1031Q | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs780306768, COSV61778600; called by muse, mutect2
- OBSCN | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 48/453 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs202099413; called by muse, mutect2, varscan2
- PA2G4 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as rs948397871; called by muse, mutect2
- PANK4 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164023262, COSV65867648; called by muse, mutect2, varscan2
- PAPSS1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1310945883, COSV54489194; called by muse, mutect2, varscan2
- PARP10 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs144061481; called by muse, mutect2, varscan2
- PATE4 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.266); catalogued as rs1312191383, COSV71919324, COSV71919429; called by muse, mutect2, varscan2
- PCDHA1 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as COSV65374886; called by muse, mutect2
- PCDHA3 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 28/1015 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); catalogued as rs915930472, COSV100793613; called by muse, mutect2
- PDPR | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 45/830 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs1394119779; called by muse, mutect2
- PEX11A | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146767422; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 26/216 reads (12%) | catalogued as rs749326031; called by mutect2, pindel
- PHF1 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs373763326, COSV53380933; called by muse, mutect2
- PI4KA | c.5560G>T p.D1854Y | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM155716; called by muse, mutect2, varscan2
- PITRM1 | c.2164G>A p.A722T | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372253193; called by muse, mutect2, varscan2
- PKLR | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV61360849; called by muse, mutect2
- PLVAP | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 27/386 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs776368180, COSV53084355; called by muse, mutect2
- PML | c.1651del p.E551Rfs*8 | Frame Shift Del (DEL) | VAF 16/178 reads (9%) | catalogued as rs1325735061, COSV99166824; called by mutect2, pindel
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 35/286 reads (12%) | catalogued as rs781891121, COSV61745231; called by mutect2, pindel
- PNMA3 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV100937670; called by muse, mutect2
- POGZ | c.2164A>G p.M722V | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs760122079; called by muse, mutect2, varscan2
- PPP6R2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs998425904, COSV53294650; called by muse, mutect2
- PRKCD | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 19/592 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as rs913175157, COSV100388175, COSV57853135; called by muse, mutect2
- PSPC1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1179471895; called by muse, mutect2
- PTEN | c.365T>A p.I122N | Missense Mutation (SNP) | VAF 48/680 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM1513160, COSV64295127, COSV64309969; called by muse, mutect2
- PTPN6 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as rs782761798, COSV100016975; called by muse, mutect2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 48/520 reads (9%) | catalogued as rs1251406873; called by mutect2, pindel
- RBBP6 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as rs779493561, COSV100155246; called by muse, mutect2, varscan2
- RBM25 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.885); catalogued as rs1242801651; called by muse, mutect2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 13/93 reads (14%) | catalogued as rs762006287; called by mutect2, varscan2
- RELCH | c.3332C>T p.T1111M | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as rs1258872150; called by muse, mutect2
- RELN | c.10073C>T p.A3358V | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs911568601; called by muse, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs759247453; called by mutect2, varscan2
- RFX3 | c.494C>T p.T165M | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as rs1278057603; called by muse, mutect2
- RFXANK | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as rs757742036, COSV57393484; called by muse, mutect2
- RHBDL3 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as COSV52188412; called by mutect2, varscan2
- RILP | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368808603, COSV53961452; called by muse, mutect2, varscan2
- ROR2 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 52/622 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.304); catalogued as rs151187583; ClinVar: uncertain significance; called by muse, mutect2
- RPTN | c.2143G>T p.D715Y | Missense Mutation (SNP) | VAF 35/387 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs766765141, COSV100285922, COSV60166408; called by muse, mutect2
- RSBN1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 33/478 reads (7%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs573352824, COSV54730756; called by muse, mutect2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | catalogued as rs771002611; called by mutect2, pindel
- SEC24B | c.2386G>A p.A796T | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs374392004; called by muse, mutect2
- SELENOF | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs1452075125; called by muse, mutect2
- SERPINI1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1307589619; called by muse, mutect2
- SHANK2 | c.4379C>T p.A1460V | Missense Mutation (SNP) | VAF 50/751 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV53612570; called by muse, mutect2
- SHROOM3 | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as rs754683739, COSV56023709; called by muse, mutect2, varscan2
- SLC20A2 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1211274033; called by muse, mutect2, varscan2
- SLC39A4 | c.413C>T p.P138L (on ENST00000301305 / NM_001374839.1; = p.P113L on NM_017767.3) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs781929804, COSV52779064; called by muse, mutect2
- SLCO3A1 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1198179473, COSV59229342; called by muse, mutect2
- SMC6 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61173220; called by muse, mutect2
- SNRPD2 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1189594663, COSV50004298; called by muse, mutect2
- SPTB | c.4892G>A p.R1631H | Missense Mutation (SNP) | VAF 37/449 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs201082918; called by muse, mutect2
- SPTB | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 36/531 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs562590442, COSV67629786, COSV67634606; called by muse, mutect2
- SREBF2 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 93/564 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.883); catalogued as COSV100761399; called by muse, mutect2, varscan2
- ST18 | c.2093del p.K698Sfs*24 | Frame Shift Del (DEL) | VAF 18/216 reads (8%) | catalogued as COSV52509029; called by mutect2, pindel
- SURF2 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.232); catalogued as COSV64332117; called by muse, mutect2
- SYNRG | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs368473938; called by muse, mutect2
- SYT16 | c.1205G>A p.G402D | Missense Mutation (SNP) | VAF 51/650 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs777461212, COSV70859134; called by muse, mutect2
- TBC1D32 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as rs1035333816; called by muse, mutect2, varscan2
- TECPR1 | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567756951; called by muse, mutect2
- TEKT5 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 50/542 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs754915834; called by muse, mutect2
- TET2 | c.5978G>A p.R1993Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as rs974556421; called by muse, mutect2
- TEX2 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as rs782479358, COSV51980367; called by muse, mutect2, varscan2
- TIMM23B | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs1264086619; called by muse, mutect2
- TLE5 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs899160634; called by muse, mutect2
- TLX1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930105; called by muse, mutect2, varscan2
- TMEM130 | c.1271C>T p.P424L (on ENST00000416379 / NM_001134450.2; = p.P412L on NM_152913.3) | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.967); catalogued as rs140882547; called by muse, mutect2
- TNC | c.4960del p.I1654Sfs*13 | Frame Shift Del (DEL) | VAF 42/514 reads (8%) | catalogued as COSV100405896; called by mutect2, pindel
- TOR1AIP2 | c.1241C>T p.T414M | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs151254233; called by muse, mutect2
- TPD52L2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 21/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99410878; called by muse, mutect2
- TRIM46 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 25/264 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs370747351; called by muse, mutect2
- TRNT1 | c.986dup p.N329Kfs*2 | Frame Shift Ins (INS) | VAF 20/158 reads (13%) | catalogued as rs1196429193; called by mutect2, pindel
- TSPYL2 | c.249del p.I84Sfs*63 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | catalogued as rs1556807263; called by mutect2, pindel, varscan2
- TSPYL2 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs782632847; called by muse, mutect2
- UHRF1BP1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs375769716; called by muse, mutect2
- ULK1 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.031); catalogued as rs748566843, COSV58859126; called by muse, mutect2, varscan2
- VN1R2 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs370380201; called by muse, mutect2, varscan2
- WDFY4 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57447005; called by muse, mutect2
- XRCC3 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 29/440 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs146507354; called by muse, mutect2
- ZBTB17 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65269207; called by muse, mutect2
- ZC3H12D | c.1334G>T p.R445L | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as rs1250041884; called by muse, mutect2, varscan2
- ZIK1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.554); catalogued as COSV56737614; called by muse, mutect2
- ZNF648 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1476067237, COSV60570001; called by muse, mutect2, varscan2
- ZNF75D | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66132589; called by muse, mutect2
- ZSWIM8 | c.4105G>A p.A1369T (on ENST00000605216 / NM_001242487.2; = p.A1374T on NM_015037.3) | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55213181; called by muse, mutect2
- ACTN3 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ADGRB1 | c.3970del p.D1324Tfs*10 | Frame Shift Del (DEL) | VAF 34/430 reads (8%) | called by mutect2, pindel
- ADGRG4 | c.4330A>T p.T1444S | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- AGAP4 | c.1304T>A p.L435Q | Missense Mutation (SNP) | VAF 205/1782 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.371A>T p.H124L | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- AKAP9 | c.6670A>G p.R2224G (on ENST00000359028; = p.R2200G on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALDH3A1 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ALPI | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANKRD35 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ANO3 | c.2066T>C p.I689T | Missense Mutation (SNP) | VAF 25/252 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP35 | c.1103del p.K368Sfs*3 | Frame Shift Del (DEL) | VAF 34/280 reads (12%) | called by mutect2, pindel
- ARHGAP6 | c.728G>A p.C243Y | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ATP1A4 | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- BCR | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- C19orf57 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.235); called by muse, mutect2
- C8orf58 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1A | c.4804C>T p.R1602W | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- CACNA1A | c.314del p.L105* | Frame Shift Del (DEL) | VAF 16/156 reads (10%) | called by mutect2, pindel
- CASC3 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 37/365 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); called by muse, mutect2
- CBX6 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2
- CCDC89 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 31/265 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CFAP65 | c.3379C>A p.L1127M | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CFL1 | c.464del p.G155Afs*75 | Frame Shift Del (DEL) | VAF 26/343 reads (8%) | called by mutect2, pindel
- CHD2 | c.1615G>C p.V539L | Missense Mutation (SNP) | VAF 19/570 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.105); called by muse, mutect2
- CLDN6 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 40/544 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- CMIP | c.2225T>C p.M742T (on ENST00000537098 / NM_198390.2; = p.M648T on NM_030629.3) | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2
- COBL | c.2350T>C p.S784P | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.139); called by muse, mutect2
- COL4A1 | c.569C>A p.P190Q | Missense Mutation (SNP) | VAF 63/813 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.838); called by muse, mutect2
- COL5A2 | c.4436C>A p.P1479H | Missense Mutation (SNP) | VAF 20/595 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUBN | c.1556del p.F519Sfs*3 | Frame Shift Del (DEL) | VAF 38/400 reads (10%) | called by mutect2, pindel
- CYP1B1 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- DCAF8L2 | c.1132A>G p.N378D | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.149); called by muse, mutect2
- DERPC | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); called by muse, mutect2
- DHX37 | c.1813-1G>T p.X605_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- DHX9 | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- DNHD1 | c.5650A>T p.T1884S | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2
- DROSHA | c.2838A>G p.I946M | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.358); called by muse, mutect2
- DSP | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 42/374 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- DSP | c.4091del p.N1364Ifs*32 | Frame Shift Del (DEL) | VAF 10/115 reads (9%) | called by mutect2, pindel
- DST | c.13779del p.R4594Dfs*6 (on ENST00000361203 / NM_001374722.1; = p.R2182Dfs*6 on NM_015548.5) | Frame Shift Del (DEL) | VAF 21/167 reads (13%) | called by mutect2, pindel, varscan2
- E2F7 | c.2687C>A p.T896N | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- ECHDC1 | c.597_600del p.V200Kfs*2 (on ENST00000531967 / NM_001139510.1; = p.V194Kfs*2 on NM_001002030.2) | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.305T>C p.L102P (on ENST00000531967 / NM_001139510.1; = p.L96P on NM_018479.3) | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- EGFL6 | c.1015del p.M339* | Frame Shift Del (DEL) | VAF 33/384 reads (9%) | called by mutect2, pindel
- FASN | c.4990C>T p.R1664W | Missense Mutation (SNP) | VAF 27/721 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- FER1L6 | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- FZD10 | c.1116G>A p.M372I | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2
- FZR1 | c.1124del p.G375Afs*14 | Frame Shift Del (DEL) | VAF 11/116 reads (9%) | called by mutect2, pindel, varscan2
- GABRB2 | c.1498dup p.S500Ffs*48 (on ENST00000274547; = p.S462Ffs*48 on NM_000813.3) | Frame Shift Ins (INS) | VAF 21/187 reads (11%) | called by mutect2, pindel
- GALNTL6 | c.1352del p.P451Rfs*28 | Frame Shift Del (DEL) | VAF 23/236 reads (10%) | called by mutect2, pindel
- GCAT | c.355del p.I119* | Frame Shift Del (DEL) | VAF 27/306 reads (9%) | called by mutect2, pindel
- GNA12 | c.685G>T p.G229C | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GNRH1 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 21/328 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- GRIN2D | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- HSBP1 | c.166A>G p.M56V | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.068); called by muse, mutect2
- HSPB9 | c.262A>T p.R88W | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2
- HSPBP1 | c.318dup p.T107Hfs*26 | Frame Shift Ins (INS) | VAF 12/121 reads (10%) | called by mutect2, pindel
- IRS2 | c.2285C>A p.P762H | Missense Mutation (SNP) | VAF 52/490 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 7/78 reads (9%) | called by mutect2, pindel
- KATNIP | c.1959G>T p.K653N | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.117); called by muse, mutect2
- KCNA6 | c.1304dup p.I437Dfs*57 | Frame Shift Ins (INS) | VAF 24/160 reads (15%) | called by mutect2, pindel, varscan2
- KCNH3 | c.3053C>A p.P1018H | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- KCNJ14 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- KCNQ3 | c.2337A>T p.R779S | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by muse, mutect2
- KDM6B | c.82T>C p.W28R | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- KIAA1549 | c.2316del p.G773Afs*8 | Frame Shift Del (DEL) | VAF 14/165 reads (8%) | called by mutect2, pindel
- KIF21A | c.387del p.K129Nfs*3 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, varscan2
- KIF4B | c.2018T>C p.I673T | Missense Mutation (SNP) | VAF 85/469 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLHL25 | c.988dup p.R330Pfs*37 | Frame Shift Ins (INS) | VAF 22/268 reads (8%) | called by mutect2, pindel
- KLHL42 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.177); called by muse, mutect2
- KMT2A | c.8993A>G p.H2998R | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- KREMEN2 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT15 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KRT18 | c.596T>A p.L199Q | Missense Mutation (SNP) | VAF 13/343 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- LRRC4B | c.1307G>A p.C436Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LUM | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); called by muse, mutect2
- MAGI3 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAP4K4 | c.2453A>G p.H818R (on ENST00000347699 / NM_001242559.2; = p.H736R on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/261 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2
- MAVS | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 61/505 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MEI1 | c.1667T>C p.I556T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- MINDY4 | c.192A>C p.E64D | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.359); called by muse, mutect2
- MRPS2 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MXRA7 | c.253del p.E85Sfs*64 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel, varscan2
- MXRA8 | c.820C>A p.L274M | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MYO18A | c.2158G>A p.G720S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.16); called by muse, mutect2
- NACC2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- NAIP | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECTIN4 | c.830del p.P277Lfs*29 | Frame Shift Del (DEL) | VAF 41/391 reads (10%) | called by mutect2, pindel
- NFE2L1 | c.485del p.P162Qfs*6 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- NKX6-3 | c.599T>G p.L200R (on ENST00000518699 / NM_001364841.2; = p.L70R on NM_152568.3) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- NMNAT2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOD2 | c.1955C>A p.S652* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- NPAS3 | c.1496A>G p.D499G (on ENST00000356141 / NM_001164749.2; = p.D467G on NM_022123.3) | Missense Mutation (SNP) | VAF 27/316 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, mutect2
- NPTX1 | c.454C>A p.R152S | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- NR4A3 | c.889dup p.D297Gfs*36 | Frame Shift Ins (INS) | VAF 5/51 reads (10%) | called by mutect2, pindel
- NRTN | c.118del p.L40Cfs*34 | Frame Shift Del (DEL) | VAF 48/439 reads (11%) | called by mutect2, pindel
- NWD2 | c.3362C>T p.T1121I | Missense Mutation (SNP) | VAF 41/399 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- OGFR | c.1105C>A p.H369N | Missense Mutation (SNP) | VAF 17/332 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.014); called by muse, mutect2
- P4HTM | c.1445del p.G482Afs*51 (on ENST00000383729 / NM_177939.3; = p.G543Afs*51 on NM_177938.2) | Frame Shift Del (DEL) | VAF 53/439 reads (12%) | called by mutect2, pindel, varscan2
- PAX2 | c.1207del p.R403Gfs*37 (on ENST00000428433 / NM_003987.5; = p.R380Gfs*37 on NM_000278.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 42/370 reads (11%) | called by pindel, varscan2
- PCDH18 | c.2751_2752del p.C918Hfs*11 | Frame Shift Del (DEL) | VAF 15/121 reads (12%) | called by pindel, varscan2
- PCNT | c.3491G>T p.R1164M | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- PELP1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.511); called by muse, mutect2
- PIGO | c.656-1G>A p.X219_splice | Splice Site (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- POLRMT | c.1705del p.L569Cfs*53 | Frame Shift Del (DEL) | VAF 26/312 reads (8%) | called by mutect2, pindel
- POMK | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PPM1A | c.952+6T>C | Splice Region (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- PPP1R16A | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRR5L | c.200del p.G67Vfs*11 | Frame Shift Del (DEL) | VAF 24/260 reads (9%) | called by mutect2, pindel
- PRRC2A | c.6079C>T p.P2027S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTGES2 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUS1 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2
- PXDN | c.2592del p.N865Mfs*25 | Frame Shift Del (DEL) | VAF 28/199 reads (14%) | called by mutect2, pindel, varscan2
- QTRT1 | c.837C>A p.D279E | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- RGS9 | c.463T>G p.W155G | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RTCB | c.736del p.M246Wfs*11 | Frame Shift Del (DEL) | VAF 26/252 reads (10%) | called by mutect2, pindel
- RTL9 | c.1076T>C p.M359T | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2
- RYR1 | c.14610G>T p.E4870D | Missense Mutation (SNP) | VAF 73/867 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); called by muse, mutect2
- SAMD9 | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SASH1 | c.627+2T>C p.X209_splice | Splice Site (SNP) | VAF 16/175 reads (9%) | called by muse, mutect2
- SCARA5 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SCNN1A | c.620C>G p.A207G | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2
- SEMA3E | c.1952C>T p.T651I | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SGF29 | c.225-1G>A p.X75_splice | Splice Site (SNP) | VAF 26/264 reads (10%) | called by muse, mutect2
- SLC26A9 | c.1821del p.T608Pfs*62 | Frame Shift Del (DEL) | VAF 34/271 reads (13%) | called by mutect2, pindel
- SLC7A4 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- SMIM30 | c.148del p.V50Yfs*28 | Frame Shift Del (DEL) | VAF 36/416 reads (9%) | called by mutect2, pindel
- SNRNP200 | c.3664dup p.W1222Lfs*16 | Frame Shift Ins (INS) | VAF 72/632 reads (11%) | called by mutect2, pindel, varscan2
- SOX17 | c.630dup p.A211Rfs*154 | Frame Shift Ins (INS) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- SOX2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- STK11IP | c.2259C>G p.D753E | Missense Mutation (SNP) | VAF 21/531 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2
- TAF5L | c.410T>A p.I137N | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2
- TAS1R2 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TASOR2 | c.3300A>C p.E1100D | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- TENM1 | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- TFRC | c.655T>C p.Y219H | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMED7 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM238 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.445); called by muse, mutect2
- TMEM263 | c.257del p.G86Vfs*17 | Frame Shift Del (DEL) | VAF 30/214 reads (14%) | called by mutect2, pindel, varscan2
- TNNT1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.53); called by muse, mutect2
- TSEN34 | c.244-1G>T p.X82_splice | Splice Site (SNP) | VAF 18/335 reads (5%) | called by muse, mutect2
- TSHZ2 | c.781del p.R261Gfs*15 | Frame Shift Del (DEL) | VAF 21/175 reads (12%) | called by mutect2, pindel, varscan2
- TSPAN1 | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR4 | c.9301del p.V3101Cfs*25 | Frame Shift Del (DEL) | VAF 40/479 reads (8%) | called by mutect2, pindel
- WDFY3 | c.5695G>A p.A1899T | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.467); called by muse, mutect2
- WDR13 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- WDR75 | c.719C>G p.T240R | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- YTHDC1 | c.1996C>T p.R666C (on ENST00000344157 / NM_001031732.4; = p.R648C on NM_133370.4) | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- YY1AP1 | c.823C>A p.L275M (on ENST00000295566 / NM_139118.2; = p.L198M on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/461 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZBED4 | c.1727_1728del p.K576Sfs*18 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- ZBTB2 | c.338T>A p.L113H | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); called by muse, mutect2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 14/161 reads (9%) | called by mutect2, pindel
- ZBTB39 | c.2099T>G p.I700S | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.01); called by muse, mutect2
- ZC3H7B | c.2857C>G p.L953V | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- ZEB1 | c.1880del p.K627Sfs*26 | Frame Shift Del (DEL) | VAF 106/992 reads (11%) | called by mutect2, pindel
- ZFHX2 | c.3004C>T p.Q1002* | Nonsense Mutation (SNP) | VAF 30/597 reads (5%) | called by muse, mutect2
- ZNF174 | c.113del p.N38Tfs*53 | Frame Shift Del (DEL) | VAF 32/331 reads (10%) | called by mutect2, pindel
- ZNF567 | c.967G>A p.A323T (on ENST00000536254 / NM_001322913.1; = p.A292T on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/295 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.247); called by muse, mutect2
- ZNF717 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF746 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF784 | c.937del p.E313Rfs*5 | Frame Shift Del (DEL) | VAF 34/296 reads (11%) | called by mutect2, pindel
- ACOX2 | c.1701G>A p.A567= | Silent (SNP) | VAF 30/425 reads (7%) | catalogued as rs767419736; called by muse, mutect2
- ACTL7B | c.630C>T p.S210= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as rs143167162; called by muse, mutect2, varscan2
- AICDA | c.198G>A p.S66= | Silent (SNP) | VAF 33/452 reads (7%) | catalogued as COSV57565821; called by muse, mutect2
- AKAP9 | c.3099A>T p.G1033= | Silent (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- ANKRD30A | c.1149C>T p.I383= (on ENST00000611781; = p.I327= on NM_052997.2) | Silent (SNP) | VAF 14/409 reads (3%) | catalogued as rs868304038, COSV100653525, COSV64606919; called by muse, mutect2
- ASS1 | c.489C>T p.Y163= | Silent (SNP) | VAF 32/464 reads (7%) | catalogued as rs377319610; called by muse, mutect2
- ATP4A | c.1389G>A p.S463= | Silent (SNP) | VAF 14/250 reads (6%) | called by muse, mutect2
- AVPR1A | c.375C>T p.R125= | Silent (SNP) | VAF 21/275 reads (8%) | catalogued as rs1165422176; called by muse, mutect2
- BICD1 | c.2406G>A p.E802= | Silent (SNP) | VAF 40/492 reads (8%) | catalogued as rs1258737426; called by muse, mutect2
- CALHM6 | c.681G>A p.E227= | Silent (SNP) | VAF 26/452 reads (6%) | called by muse, mutect2
- CAMSAP1 | c.2796G>A p.P932= | Silent (SNP) | VAF 28/328 reads (9%) | catalogued as rs144732198; called by muse, mutect2
- CAMSAP3 | c.1038C>T p.N346= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1293C>T p.L431= | Silent (SNP) | VAF 24/396 reads (6%) | catalogued as rs1265613862, COSV57907773; called by muse, mutect2
- CCDC88C | c.1518C>T p.L506= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1418726324; called by muse, mutect2
- CD40 | c.381C>T p.P127= | Silent (SNP) | VAF 22/260 reads (8%) | catalogued as rs763263083, COSV64848233; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- CHADL | c.298C>T p.L100= | Silent (SNP) | VAF 18/256 reads (7%) | called by muse, mutect2
- COL6A6 | c.5442C>T p.R1814= | Silent (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- DCLK3 | c.1407C>T p.H469= | Silent (SNP) | VAF 24/203 reads (12%) | catalogued as rs747503381, COSV101373941; called by muse, mutect2, varscan2
- DGKK | c.99G>A p.P33= | Silent (SNP) | VAF 10/203 reads (5%) | catalogued as COSV101052996; called by muse, mutect2
- DICER1 | c.4860C>T p.S1620= | Silent (SNP) | VAF 30/690 reads (4%) | called by muse, mutect2
- DIP2C | c.3303G>A p.A1101= | Silent (SNP) | VAF 36/475 reads (8%) | catalogued as rs759847812, COSV55181803, COSV99791927; called by muse, mutect2
- EGLN2 | c.870C>T p.N290= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as rs1252769073, COSV100393657; called by muse, mutect2
- F8 | c.453A>G p.G151= | Silent (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- FAIM | c.57C>T p.I19= | Silent (SNP) | VAF 26/235 reads (11%) | catalogued as rs148507350, COSV58159472; called by muse, mutect2, varscan2
- FAM178B | c.1545C>T p.D515= | Silent (SNP) | VAF 26/253 reads (10%) | catalogued as rs1255302717; called by muse, mutect2
- FIGNL2 | c.459G>A p.S153= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV73729255; called by muse, mutect2
- FOXC2 | c.663G>A p.A221= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- FOXI2 | c.237C>T p.G79= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- FUS | c.1114C>A p.R372= | Silent (SNP) | VAF 20/322 reads (6%) | called by muse, mutect2
- GAL3ST1 | c.60G>A p.A20= | Silent (SNP) | VAF 25/314 reads (8%) | catalogued as rs752866163; called by muse, mutect2
- GLI3 | c.3468C>T p.T1156= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs1404166318, COSV67891884; called by muse, mutect2, varscan2
- GLUD2 | c.282C>T p.S94= | Silent (SNP) | VAF 47/1010 reads (5%) | called by muse, mutect2
- GNB2 | c.879C>T p.N293= | Silent (SNP) | VAF 26/320 reads (8%) | catalogued as rs151109351; called by muse, mutect2
- GRID2 | c.192A>G p.T64= | Silent (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- GRIN3B | c.2577G>A p.A859= | Silent (SNP) | VAF 23/197 reads (12%) | catalogued as rs143329396; called by muse, mutect2, varscan2
- GSG1 | c.423G>A p.A141= | Silent (SNP) | VAF 30/288 reads (10%) | catalogued as rs368946693; called by muse, mutect2, varscan2
- HECTD4 | c.2358A>G p.E786= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- INTS2 | c.195T>A p.A65= | Silent (SNP) | VAF 13/225 reads (6%) | called by muse, mutect2
- ITGB3 | c.1833C>T p.S611= | Silent (SNP) | VAF 27/661 reads (4%) | catalogued as rs898481102; called by muse, mutect2
- KAZN | c.1038C>T p.S346= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as rs772949355; called by muse, mutect2
- KCNMB1 | c.357C>T p.D119= | Silent (SNP) | VAF 22/254 reads (9%) | catalogued as rs772278093, COSV51131148; called by muse, mutect2
- KRT71 | c.189C>T p.S63= | Silent (SNP) | VAF 60/286 reads (21%) | catalogued as rs750271411, COSV57291223; called by muse, mutect2, varscan2
- LGALS8 | c.285G>A p.T95= | Silent (SNP) | VAF 49/506 reads (10%) | catalogued as rs146419217; called by muse, mutect2, varscan2
- LGI4 | c.537C>T p.S179= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as rs1251055769; called by muse, mutect2
- LIMCH1 | c.1353C>A p.T451= | Silent (SNP) | VAF 15/445 reads (3%) | called by muse, mutect2
- LPAR5 | c.547C>T p.L183= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- LRCH4 | c.1416A>T p.G472= | Silent (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- LRFN4 | c.1719G>A p.P573= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as rs1425364826; called by muse, mutect2
- LVRN | c.459C>T p.C153= | Silent (SNP) | VAF 29/379 reads (8%) | called by muse, mutect2
- MAP3K9 | c.2688G>A p.L896= (on ENST00000554752 / NM_001284230.1; = p.L910= on NM_033141.4) | Silent (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- MBD5 | c.1164G>A p.Q388= | Silent (SNP) | VAF 70/757 reads (9%) | catalogued as COSV68695892; called by muse, mutect2
- MROH1 | c.315C>T p.D105= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- MUC12 | c.14478A>G p.S4826= (on ENST00000379442; = p.S4683= on NM_001164462.1) | Silent (SNP) | VAF 20/553 reads (4%) | catalogued as rs935448984, COSV65190073; called by muse, mutect2
- NBAS | c.1917C>A p.S639= | Silent (SNP) | VAF 11/189 reads (6%) | called by muse, mutect2
- NEU1 | c.666G>A p.T222= | Silent (SNP) | VAF 43/371 reads (12%) | catalogued as rs370667977, COSV99999030; called by muse, mutect2, varscan2
- NLRP5 | c.1542C>T p.G514= | Silent (SNP) | VAF 36/392 reads (9%) | catalogued as rs779756665, COSV66767046; called by muse, mutect2
- OPN1LW | c.618C>T p.D206= | Silent (SNP) | VAF 37/640 reads (6%) | catalogued as rs1459231886, COSV100885073; called by muse, mutect2
- OR5M10 | c.315C>T p.I105= | Silent (SNP) | VAF 33/326 reads (10%) | catalogued as rs528316710, COSV73242361; called by muse, mutect2
- OTOP2 | c.621C>T p.S207= | Silent (SNP) | VAF 20/190 reads (11%) | catalogued as COSV58882921; called by muse, mutect2
- OTX1 | c.501G>A p.S167= | Silent (SNP) | VAF 26/224 reads (12%) | called by muse, mutect2, varscan2
- PCDH17 | c.2184C>T p.V728= | Silent (SNP) | VAF 15/209 reads (7%) | catalogued as COSV64973231; called by muse, mutect2
- PCDHA11 | c.1563G>A p.P521= | Silent (SNP) | VAF 119/1188 reads (10%) | catalogued as rs782557554, COSV56488573, COSV56555599; called by muse, mutect2
- PCDHA3 | c.1914C>T p.D638= | Silent (SNP) | VAF 33/242 reads (14%) | catalogued as COSV63540718; called by muse, mutect2, varscan2
- PCDHB15 | c.1224G>A p.A408= | Silent (SNP) | VAF 24/322 reads (7%) | catalogued as COSV51428249; called by muse, mutect2
- PCDHB6 | c.1443C>T p.N481= | Silent (SNP) | VAF 163/1062 reads (15%) | catalogued as rs782588902, COSV50689519; called by muse, mutect2, varscan2
- PCDHB9 | c.1992C>T p.D664= | Silent (SNP) | VAF 52/653 reads (8%) | catalogued as rs781854112; called by muse, mutect2
- PCDHGA5 | c.1743C>T p.S581= | Silent (SNP) | VAF 56/474 reads (12%) | catalogued as rs766163319, COSV54051774; called by muse, mutect2, varscan2
- PDE11A | c.2517C>T p.F839= | Silent (SNP) | VAF 43/284 reads (15%) | catalogued as rs778256443, COSV53704090; called by muse, mutect2, varscan2
- PELP1 | c.2370C>T p.I790= | Silent (SNP) | VAF 14/216 reads (6%) | catalogued as rs958252926; called by muse, mutect2
- PIK3C2A | c.1902A>G p.S634= | Silent (SNP) | VAF 24/317 reads (8%) | called by muse, mutect2
- PLEKHG1 | c.3450T>C p.S1150= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- PLVAP | c.462C>T p.C154= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as rs1423337722, COSV53087963; called by muse, mutect2
- PPP3R2 | c.258C>T p.G86= | Silent (SNP) | VAF 28/375 reads (7%) | catalogued as COSV62453547; called by muse, mutect2
- PRAF2 | c.102C>T p.C34= | Silent (SNP) | VAF 29/387 reads (7%) | called by muse, mutect2
- RASGEF1C | c.507G>A p.G169= | Silent (SNP) | VAF 55/652 reads (8%) | called by muse, mutect2
- RENBP | c.339G>A p.K113= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- RFTN2 | c.1122C>T p.S374= | Silent (SNP) | VAF 16/183 reads (9%) | catalogued as rs750192183; called by muse, mutect2
- RRS1 | c.1053C>T p.G351= | Silent (SNP) | VAF 18/261 reads (7%) | called by muse, mutect2
- SCARA5 | c.798C>T p.H266= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as rs1323562201; called by muse, mutect2, varscan2
- SCRT1 | c.582C>T p.G194= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- SCYL3 | c.699G>A p.R233= | Silent (SNP) | VAF 15/235 reads (6%) | called by muse, mutect2
- SEZ6L2 | c.1758C>T p.D586= (on ENST00000308713 / NM_001114099.3; = p.D516= on NM_012410.4) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs893483588, COSV58098906; called by muse, mutect2
- SIX2 | c.72C>T p.G24= | Silent (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- SLC26A5 | c.1797A>T p.V599= | Silent (SNP) | VAF 48/493 reads (10%) | called by muse, mutect2
- SLC7A6 | c.1077C>T p.I359= | Silent (SNP) | VAF 19/263 reads (7%) | called by muse, mutect2
- SLC9A1 | c.645C>T p.G215= | Silent (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
- SLCO5A1 | c.2499G>A p.A833= | Silent (SNP) | VAF 17/223 reads (8%) | catalogued as COSV52661816, COSV99481199; called by muse, mutect2
- SLCO6A1 | c.264C>A p.P88= | Silent (SNP) | VAF 37/351 reads (11%) | catalogued as COSV65805463; called by muse, mutect2, varscan2
- SLITRK2 | c.1032T>C p.C344= | Silent (SNP) | VAF 28/247 reads (11%) | called by muse, mutect2, varscan2
- SNRNP200 | c.2539C>T p.L847= | Silent (SNP) | VAF 24/726 reads (3%) | called by muse, mutect2
- SYNJ2 | c.1200C>T p.I400= | Silent (SNP) | VAF 24/291 reads (8%) | catalogued as rs141957604; called by muse, mutect2
- TALDO1 | c.723G>A p.T241= | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs201368721; called by muse, mutect2
- TDRKH | c.324G>A p.V108= | Silent (SNP) | VAF 18/231 reads (8%) | called by muse, mutect2
- TENT5B | c.459C>T p.D153= | Silent (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- TERT | c.657G>A p.P219= | Silent (SNP) | VAF 27/229 reads (12%) | called by muse, mutect2, varscan2
- THAP11 | c.327G>A p.Q109= | Silent (SNP) | VAF 74/634 reads (12%) | catalogued as rs1191465639; called by mutect2, varscan2
- TPM2 | c.759C>T p.I253= | Silent (SNP) | VAF 48/622 reads (8%) | catalogued as rs1057524292, COSV61404585; ClinVar: likely benign; called by muse, mutect2
- TRIM24 | c.2070C>T p.S690= (on ENST00000343526 / NM_015905.3; = p.S656= on NM_003852.4) | Silent (SNP) | VAF 40/410 reads (10%) | catalogued as rs1251273587; called by muse, mutect2
- TUBGCP6 | c.5082C>T p.C1694= | Silent (SNP) | VAF 58/781 reads (7%) | catalogued as rs771445426; ClinVar: uncertain significance; called by muse, mutect2
- UBQLNL | c.639C>T p.R213= | Silent (SNP) | VAF 33/355 reads (9%) | called by muse, mutect2
- UHRF1 | c.825C>T p.D275= (on ENST00000612630 / NM_001290050.1; = p.D288= on NM_013282.4) | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs372527212; called by muse, mutect2, varscan2
- USH2A | c.14739C>T p.N4913= | Silent (SNP) | VAF 51/573 reads (9%) | catalogued as rs774695239, COSV56451484; called by muse, mutect2
- USP42 | c.1455C>T p.N485= | Silent (SNP) | VAF 25/277 reads (9%) | catalogued as rs747137240; called by muse, mutect2
- VSNL1 | c.534C>T p.D178= | Silent (SNP) | VAF 21/254 reads (8%) | called by muse, mutect2
- VWC2 | c.33G>A p.A11= | Silent (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2
- WDR97 | c.4740G>A p.P1580= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- YY2 | c.954C>T p.C318= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as COSV63411764; called by muse, mutect2
- ZFHX3 | c.9882G>A p.A3294= | Silent (SNP) | VAF 31/438 reads (7%) | catalogued as rs756457941, COSV51730371; called by muse, mutect2
- ZMYM3 | c.2511A>T p.P837= | Silent (SNP) | VAF 27/248 reads (11%) | called by muse, mutect2, varscan2
- ZNF226 | c.2142T>C p.L714= | Silent (SNP) | VAF 29/248 reads (12%) | catalogued as rs201536922; called by muse, mutect2, varscan2
- ZNF420 | c.1155C>T p.H385= | Silent (SNP) | VAF 43/353 reads (12%) | catalogued as COSV58495726; called by muse, mutect2, varscan2
- ZNF629 | c.603C>T p.T201= | Silent (SNP) | VAF 16/136 reads (12%) | catalogued as rs754125174, COSV52697473, COSV52697671; called by muse, mutect2, varscan2
- ZSWIM1 | c.469C>T p.L157= | Silent (SNP) | VAF 28/278 reads (10%) | catalogued as rs1031066115; called by muse, mutect2
- AGAP1 | c.164-38335C>T | Intron (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- AL353753.1 | n.632C>T | RNA (SNP) | VAF 20/216 reads (9%) | catalogued as rs1364035332; called by muse, mutect2
- AL353804.6 | chrX:73831125 C>T | 3'Flank (SNP) | VAF 40/444 reads (9%) | called by muse, mutect2
- AP002414.1 | n.169G>T | RNA (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2
- ARMC6 | c.*147del | 3'UTR (DEL) | VAF 16/72 reads (22%) | catalogued as rs1461765265; called by mutect2, varscan2
- ATP5F1E | c.-43C>T | 5'UTR (SNP) | VAF 31/447 reads (7%) | catalogued as rs1403787722; called by muse, mutect2
- BBS1 | c.830+12C>T | Intron (SNP) | VAF 105/559 reads (19%) | catalogued as rs781283997, COSV100567915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C10orf143 | c.69+4332C>T | Intron (SNP) | VAF 70/555 reads (13%) | catalogued as rs757855468; called by muse, mutect2, varscan2
- CSRNP1 | c.-88C>T | 5'UTR (SNP) | VAF 6/54 reads (11%) | catalogued as rs911163420; called by muse, mutect2, varscan2
- CYP21A1P | chr6:32009730 G>A | 3'Flank (SNP) | VAF 88/1107 reads (8%) | catalogued as rs1163395625; called by muse, mutect2
- DLL1 | c.-32del | 5'UTR (DEL) | VAF 12/165 reads (7%) | called by mutect2, pindel
- EIF2B4 | c.*6del | 3'UTR (DEL) | VAF 60/577 reads (10%) | catalogued as rs768539625; called by mutect2, pindel
- ELN | c.196+44T>C | Intron (SNP) | VAF 28/410 reads (7%) | called by muse, mutect2
- FARP2 | c.1893+1663C>T | Intron (SNP) | VAF 16/316 reads (5%) | catalogued as rs1452009377; called by muse, mutect2
- FLNA | c.1828+51C>T | Intron (SNP) | VAF 31/650 reads (5%) | called by muse, mutect2
- GCNT2 | c.925+27347del | Intron (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- HDAC8 | c.*387G>A | 3'UTR (SNP) | VAF 11/243 reads (5%) | called by muse, mutect2
- HPS3 | c.217+26C>T | Intron (SNP) | VAF 15/208 reads (7%) | called by muse, mutect2
- IGHV3-49 | c.-6C>T | 5'UTR (SNP) | VAF 13/136 reads (10%) | catalogued as rs782350358; called by muse, mutect2
- IMMP2L | c.239+94392C>A | Intron (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- IZUMO4 | c.397+31G>A | Intron (SNP) | VAF 20/233 reads (9%) | catalogued as rs754828139; called by muse, mutect2
- KCTD1 | c.-15-46346C>T | Intron (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- LINC01460 | n.563C>T | RNA (SNP) | VAF 11/120 reads (9%) | catalogued as rs1272701565; called by muse, mutect2
- MAT1A | c.-23C>T | 5'UTR (SNP) | VAF 64/720 reads (9%) | catalogued as rs767638556, COSV100944440; ClinVar: uncertain significance; called by muse, mutect2
- MED23 | c.3472-10G>A | Intron (SNP) | VAF 15/361 reads (4%) | catalogued as rs1373549531; called by muse, mutect2
- MIR19B2 | n.42C>T | RNA (SNP) | VAF 14/115 reads (12%) | catalogued as rs767452610; called by muse, mutect2, varscan2
- MTNR1B | chr11:92984875 G>A | 3'Flank (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- MVB12A | c.286+350G>A | Intron (SNP) | VAF 31/242 reads (13%) | called by muse, mutect2, varscan2
- MYH11 | c.4578+23del | Intron (DEL) | VAF 68/646 reads (11%) | called by mutect2, pindel
- MYOT | c.-8A>G | 5'UTR (SNP) | VAF 19/375 reads (5%) | called by muse, mutect2
- NRG1 | c.1269-480G>A | Intron (SNP) | VAF 23/279 reads (8%) | catalogued as COSV55148220; called by muse, mutect2
- OAT | c.772-10del | Intron (DEL) | VAF 29/259 reads (11%) | catalogued as rs778743727; called by mutect2, varscan2
- OPRM1 | c.-32C>T | 5'UTR (SNP) | VAF 23/252 reads (9%) | catalogued as rs1192472956; called by muse, mutect2
- OR52I1 | c.-264T>C | 5'UTR (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- OSM | c.-2G>A | 5'UTR (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- PABPN1L | c.*146C>T | 3'UTR (SNP) | VAF 12/108 reads (11%) | catalogued as rs1028028541; called by muse, mutect2
- PDZD7 | c.-93G>T | 5'UTR (SNP) | VAF 22/331 reads (7%) | called by muse, mutect2
- PHACTR1 | c.1448-3del | Intron (DEL) | VAF 14/122 reads (11%) | catalogued as rs771327107; called by mutect2, varscan2
- PHLDB1 | c.2737-27T>C | Intron (SNP) | VAF 61/375 reads (16%) | catalogued as COSV61878624; called by muse, mutect2, varscan2
- PKN2 | c.1676+93dup | Intron (INS) | VAF 18/176 reads (10%) | called by mutect2, pindel
- PON3 | c.778-15C>A | Intron (SNP) | VAF 24/542 reads (4%) | called by muse, mutect2
- PPP4R1L | n.777A>T | RNA (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- PRCD | chr17:76544726 G>T | 3'Flank (SNP) | VAF 88/1011 reads (9%) | called by muse, mutect2
- PRICKLE3 | c.312+122C>T | Intron (SNP) | VAF 8/87 reads (9%) | catalogued as rs781881111, COSV54294688; called by muse, mutect2
- PTPN7 | c.989+15G>A | Intron (SNP) | VAF 19/187 reads (10%) | called by muse, varscan2
- REXO2 | c.422-12G>A | Intron (SNP) | VAF 11/48 reads (23%) | catalogued as rs764665235; called by muse, mutect2, varscan2
- SERINC5 | c.1238+2410C>T | Intron (SNP) | VAF 20/240 reads (8%) | catalogued as rs770748569; called by muse, mutect2
- SH3TC2 | c.280-1326del | Intron (DEL) | VAF 11/71 reads (15%) | catalogued as rs752479043; called by mutect2, varscan2
- SORBS1 | c.2128+1070C>A | Intron (SNP) | VAF 28/132 reads (21%) | called by muse, mutect2, varscan2
- SPATA21 | c.35-3582G>A | Intron (SNP) | VAF 12/282 reads (4%) | catalogued as rs990187150; called by muse, mutect2
- SSX6P | n.276C>T | RNA (SNP) | VAF 14/242 reads (6%) | catalogued as rs1460177666; called by muse, mutect2
- STON1 | chr2:48530123 del C | 5'Flank (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel
- TAOK2 | chr16:29991478 del C | 3'Flank (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel, varscan2
- TPI1 | c.*260G>A | 3'UTR (SNP) | VAF 72/832 reads (9%) | catalogued as rs782764628; ClinVar: uncertain significance; called by muse, mutect2
- WBP2 | c.655+83A>C | Intron (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438938 C>T | 5'Flank (SNP) | VAF 19/515 reads (4%) | called by muse, mutect2
- XIAP | chrX:123860227 C>A | 5'Flank (SNP) | VAF 38/424 reads (9%) | called by muse, mutect2
